Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7AY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7AY-01A (Primary Tumor).

[page 1 of 3]
(152.1cm 69.2kg BSA: 1.71m²)

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODES:
Five lymph nodes, no tumor present. (0/5)
- (B) RIGHT PELVIC LYMPH NODES:
Three lymph nodes, no tumor present. (0/3)
- (C) ANTERIOR BLADDER NECK:
Smooth muscle and adipose tissue consistent with bladder neck tissue, no tumor or prostatic glands present.
- (D) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

CSCF ICD-O-3
Adenocarcinoma, acinar
8140/3
path
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
JW 8/22/13

GROSS DESCRIPTION

- (A) LEFT PELVIC LYMPH NODE – Received is adipose tissue with lymph nodes measuring 6.5 x 5 x 1.5 cm.
SECTION CODE: A1, two possible lymph nodes; A2, A3, each containing one possible bisected lymph node; A4, one possible lymph node.
- (B) RIGHT PELVIC LYMPH NODES – Received is adipose tissue with possible lymph nodes measuring 4.5 x 3.5 x 1.2 cm.
SECTION CODE: B1, B2, each containing one possible lymph node; B3, one possible lymph node.
- (C) ANTERIOR BLADDER NECK TISSUE – Received are two pieces of pale-tan soft tissue measuring 2.5 x 1.7 x 0.7 cm. The specimen is submitted into cassette C.
Supplemental report to follow.
- (D) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
(152.1cm 69.2kg BSA: 1.71m²)

Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

- (D) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3). (SEE COMMENT)
TUMOR CONFINED TO THE PROSTATE.
MARGINS OF RESECTION FREE OF TUMOR.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.
PERINEURAL INVASION PRESENT.
No vascular/lymphatic invasion identified.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the right posterolateral, right posterior, mid posterior, and left posterior peripheral zone. The tumor focus measures 2.5 x 0.9 cm in the largest cross-sectional dimension, and it is present in the three cross sections of the prostate, extensively in the apex and focally in the base region. The tumor is confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(D) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.2 x 2.5 x 3.8 cm, 36 grams, post-fixation) has the usual shape. The soft tissue present along the posterolateral aspect of the prostate is abundant and more extensive along the right side. An area of firmness is noted on the midline posterior surface of the prostate. Serial cross sections after fixation demonstrate an area of tumor in the mid posterior region of the two cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D3, right seminal vesicle and segment of right vas deferens from the base towards the tip; D4, D5, left seminal vesicle and segment of left vas deferens from the base towards the tip; D6, prostatic base right border; D7-D9, prostatic base right posterior border; D10-D12, prostatic base central portion; D13, D14, prostatic base left border; D15, D16, prostatic base left posterior border; D17, D18, apex anterior; D19, D20, apex left; D21, D22, apex posterior; D23, D24, apex right; D25-D36, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (D7, 8, 10-12, 19-24, 27, 28, 32 and 36) and orange ink (D31) denote surfaces that do not represent a true margin of resection. Two blocks (D25 and 29) submitted for decalcification.

SNOMED CODES

[page 3 of 3]
[REDACTED] (152.1cm 69.2kg BSA: 1.71m²)

Specimen Date/Time: [REDACTED]

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 63c130c7-abb2-442c-951f-ad490131f8e6 (TCGA-KK-A7AY.BA64AA42-00AD-4DAD-ABE7-BDDC253B9B45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).